Somatic mutation profile of tumor specimen C3L-02202-01 (aliquot CPT0203350005) from CPTAC case C3L-02202, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 61.9 years (22,609 days).
Specimen C3L-02202-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45fb8519-4fa4-4130-9a3a-e4fbaaf7446e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02202-31 (Blood Derived Normal), aliquot CPT0204040002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c60b436-31cd-44cb-bc61-7f59d3a914ab

The open-access MAF lists 93 somatic variants for this specimen: 68 protein-altering or splice-affecting, 14 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 14, Nonsense Mutation 10, Intron 7, Frame Shift Del 5, Splice Site 2, Frame Shift Ins 2, 3'UTR 2, Nonstop Mutation 1, RNA 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.341-2A>T p.X114_splice | Splice Site (SNP) | VAF 66/318 reads (21%) | hotspot (GDC flag); catalogued as CS071275, COSV56542830, COSV56544966, COSV56548666, COSV56554645; called by muse, mutect2, varscan2
- ABRAXAS1 | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.118); catalogued as rs768405316, COSV58948098; called by muse, mutect2, varscan2
- CDH10 | c.1285del p.D429Tfs*49 | Frame Shift Del (DEL) | VAF 33/308 reads (11%) | catalogued as COSV100049740; called by mutect2, varscan2
- EARS2 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs758275306; called by muse, mutect2, varscan2
- EPHA4 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56025667; called by muse, mutect2
- GABRA4 | c.689C>A p.T230N | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1380833023, COSV99974915; called by muse, mutect2
- MS4A2 | c.309G>T p.W103C | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV99627121; called by muse, mutect2
- NOTCH2 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 115/736 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as rs368671802; called by muse, mutect2, varscan2
- REG1B | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 44/494 reads (9%) | catalogued as rs185604160, COSV59304330, COSV59306460; called by muse, mutect2
- SETDB1 | c.2021A>T p.K674M | Missense Mutation (SNP) | VAF 52/450 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV54990954; called by muse, mutect2, varscan2
- TRIM38 | c.270A>T p.E90D | Missense Mutation (SNP) | VAF 49/299 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs1357277319; called by muse, mutect2, varscan2
- TRIM71 | c.1661C>G p.P554R | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101070413, COSV67470348; called by muse, mutect2, varscan2
- TTN | c.4712C>T p.S1571F (on ENST00000591111; = p.S1525F on NM_003319.4) | Missense Mutation (SNP) | VAF 30/486 reads (6%) | PolyPhen benign (0.003); catalogued as COSV60260972, COSV60410943; called by muse, mutect2
- UGT2B4 | c.14G>A p.W5* | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | catalogued as COSV59318026, COSV59318944; called by muse, mutect2
- WDR5 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1386272394; called by muse, mutect2, varscan2
- ZNF17 | c.1252G>T p.E418* | Nonsense Mutation (SNP) | VAF 25/156 reads (16%) | catalogued as COSV56921369; called by muse, mutect2, varscan2
- ADGRV1 | c.11322dup p.G3775Wfs*13 | Frame Shift Ins (INS) | VAF 91/382 reads (24%) | called by mutect2, pindel, varscan2
- ARHGAP18 | c.1306C>G p.L436V | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2
- ASH2L | c.248A>T p.D83V | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.229); called by muse, mutect2
- ATL1 | c.1119G>A p.E373= | Splice Region (SNP) | VAF 67/553 reads (12%) | called by muse, mutect2, varscan2
- CCN1 | c.1062del p.K354Nfs*77 | Frame Shift Del (DEL) | VAF 33/267 reads (12%) | called by mutect2, pindel, varscan2
- CDK6 | c.499G>C p.A167P | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CENPE | c.6767C>T p.T2256I | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHD9 | c.7906del p.S2636Vfs*24 (on ENST00000398510 / NM_001382353.1; = p.S2620Vfs*24 on NM_025134.7) | Frame Shift Del (DEL) | VAF 45/293 reads (15%) | called by mutect2, pindel, varscan2
- CMBL | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- CNOT1 | c.5740C>T p.Q1914* | Nonsense Mutation (SNP) | VAF 54/562 reads (10%) | called by muse, mutect2
- CNOT1 | c.4174T>G p.C1392G | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- CPED1 | c.549A>C p.R183S | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPSF1 | c.826+1G>C p.X276_splice | Splice Site (SNP) | VAF 20/259 reads (8%) | called by muse, mutect2
- CRACR2A | c.1888_1889dup p.Q631Sfs*11 | Frame Shift Ins (INS) | VAF 43/358 reads (12%) | called by mutect2, pindel, varscan2
- DDIAS | c.617C>A p.A206D | Missense Mutation (SNP) | VAF 44/319 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DLAT | c.1252G>A p.G418S | Missense Mutation (SNP) | VAF 97/635 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- DRAM1 | c.35C>G p.P12R | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUSP11 | c.771del p.S258Vfs*88 | Frame Shift Del (DEL) | VAF 19/125 reads (15%) | called by mutect2, pindel, varscan2
- EYA4 | c.1430T>A p.V477E (on ENST00000531901 / NM_001301013.1; = p.V471E on NM_004100.5) | Missense Mutation (SNP) | VAF 83/456 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAM53A | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 23/373 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPAT3 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 46/285 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- HIPK3 | c.1390A>G p.R464G | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- IFT88 | c.1732A>T p.S578C (on ENST00000319980 / NM_001318493.2; = p.S569C on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); called by muse, mutect2
- IL1RL2 | c.1581G>C p.K527N | Missense Mutation (SNP) | VAF 23/390 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2
- IMPA1 | c.239T>C p.I80T | Missense Mutation (SNP) | VAF 31/346 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2
- KCTD12 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- LEPR | c.338C>A p.S113* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- LIPG | c.1124C>T p.T375I | Missense Mutation (SNP) | VAF 17/534 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); called by muse, mutect2
- LRP2 | c.11780C>G p.P3927R | Missense Mutation (SNP) | VAF 48/530 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2
- MSH6 | c.2842G>T p.E948* | Nonsense Mutation (SNP) | VAF 20/150 reads (13%) | called by muse, mutect2, varscan2
- MUC12 | c.2192A>G p.E731G (on ENST00000379442; = p.E588G on NM_001164462.1) | Missense Mutation (SNP) | VAF 60/1386 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.413); called by muse, mutect2
- MUC2 | c.1384T>A p.S462T | Missense Mutation (SNP) | VAF 78/521 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NBEAL1 | c.8085A>C p.*2695Cext*13 | Nonstop Mutation (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- NOP14 | c.2299A>G p.T767A | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHACTR1 | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 56/354 reads (16%) | called by muse, mutect2, varscan2
- PRDX3 | c.452G>A p.G151D | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RSU1 | c.72C>G p.D24E | Missense Mutation (SNP) | VAF 37/341 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SARM1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 24/445 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2
- SCAF8 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SELP | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- SERAC1 | c.1882A>G p.K628E | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC47A1 | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SMARCB1 | c.565C>A p.P189T (on ENST00000263121; = p.P235T on NM_003073.5) | Missense Mutation (SNP) | VAF 72/514 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- TAAR6 | c.754A>G p.R252G | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- TTC23L | c.736G>T p.A246S | Missense Mutation (SNP) | VAF 18/338 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2
- TTC3 | c.3270A>C p.E1090D | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- VPS13A | c.9080C>T p.A3027V | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.098); called by muse, mutect2
- XYLT1 | c.1997C>T p.S666F | Missense Mutation (SNP) | VAF 23/264 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.098); called by muse, mutect2
- ZFHX2 | c.5335_5336delinsA p.S1779Tfs*6 | Frame Shift Del (DEL) | VAF 34/255 reads (13%) | called by pindel, varscan2*
- ZNF441 | c.1687C>T p.Q563* | Nonsense Mutation (SNP) | VAF 51/273 reads (19%) | called by muse, mutect2, varscan2
- ZNF608 | c.2104G>C p.A702P | Missense Mutation (SNP) | VAF 65/227 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZNF804B | c.2390C>G p.S797* | Nonsense Mutation (SNP) | VAF 21/216 reads (10%) | called by muse, mutect2
- ANO7 | c.495C>G p.T165= (on ENST00000274979; = p.T111= on NM_001370694.2) | Silent (SNP) | VAF 69/432 reads (16%) | called by muse, mutect2, varscan2
- CETP | c.853C>A p.R285= | Silent (SNP) | VAF 46/355 reads (13%) | catalogued as CM983856, COSV99569878; called by muse, mutect2
- DAB1 | c.1299T>C p.S433= (on ENST00000371231; = p.S400= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 22/164 reads (13%) | catalogued as rs1405519334; called by muse, mutect2, varscan2
- DDX31 | c.1278A>T p.T426= | Silent (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- EEPD1 | c.972C>A p.R324= | Silent (SNP) | VAF 42/501 reads (8%) | called by muse, mutect2
- FSIP2 | c.10491A>G p.Q3497= | Silent (SNP) | VAF 18/145 reads (12%) | called by muse, mutect2, varscan2
- KIF6 | c.2160C>A p.S720= | Silent (SNP) | VAF 33/209 reads (16%) | called by muse, mutect2, varscan2
- MUC17 | c.5010A>T p.S1670= | Silent (SNP) | VAF 38/269 reads (14%) | called by muse, mutect2, varscan2
- NEB | c.4371G>C p.V1457= | Silent (SNP) | VAF 40/468 reads (9%) | called by muse, mutect2
- NNT | c.126G>A p.L42= | Silent (SNP) | VAF 28/225 reads (12%) | called by muse, mutect2, varscan2
- PET117 | c.217T>C p.L73= | Silent (SNP) | VAF 24/98 reads (24%) | called by muse, mutect2, varscan2
- SECISBP2 | c.1746G>A p.E582= | Silent (SNP) | VAF 98/614 reads (16%) | called by muse, mutect2, varscan2
- SFMBT2 | c.2505G>T p.L835= | Silent (SNP) | VAF 65/407 reads (16%) | called by muse, mutect2, varscan2
- TM2D3 | c.606C>T p.D202= (on ENST00000333202 / NM_078474.3; = p.D176= on NM_025141.3) | Silent (SNP) | VAF 32/169 reads (19%) | called by muse, mutect2, varscan2
- CABP1 | c.655-3872G>A | Intron (SNP) | VAF 23/153 reads (15%) | catalogued as rs764132379; called by muse, mutect2, varscan2
- CAMK2B | c.342-16C>G | Intron (SNP) | VAF 31/282 reads (11%) | catalogued as rs771941070; called by muse, mutect2, varscan2
- COQ5 | c.202+2471C>G | Intron (SNP) | VAF 24/170 reads (14%) | catalogued as rs958560105; called by muse, mutect2, varscan2
- IGLV8OR8-1 | n.181C>G | RNA (SNP) | VAF 10/191 reads (5%) | called by muse, mutect2
- MAN1B1 | c.1255-215C>A | Intron (SNP) | VAF 23/501 reads (5%) | called by muse, mutect2
- RBFOX2 | c.*7G>A | 3'UTR (SNP) | VAF 13/99 reads (13%) | catalogued as rs371844393; called by muse, mutect2, varscan2
- RBMS2 | c.543-888del | Intron (DEL) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- RGS6 | c.*303G>A | 3'UTR (SNP) | VAF 9/243 reads (4%) | catalogued as rs1181390807; called by muse, mutect2
- TAF15 | c.-86A>G | 5'UTR (SNP) | VAF 51/515 reads (10%) | catalogued as rs1469988615; called by muse, mutect2
- TP63 | c.580-19965G>T | Intron (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- Z82190.2 | c.1787-18022T>A | Intron (SNP) | VAF 60/386 reads (16%) | called by mutect2, varscan2
